Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A0MI, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A0MI-01A (Primary Tumor).

[page 1 of 2]
1CD-0-3

adenocarcinoma, endometrioid, NOS 8380/3

Site: Endometrium C54.1 per 5/3/11

FINAL DIAGNOSIS:

PART 1: BLADDER FLAP IMPLANT, BIOPSY -
SOFT TISSUE, NEGATIVE FOR MALIGNANCY.

PART 2: UTERINE SEROSA, BIOPSY -
FRAGMENT OF SMOOTH MUSCLE, NEGATIVE FOR MALIGNANCY.

PART 3: UTERUS WITH CERVIX AND BILATERAL ADNEXA, TOTAL ABDOMINAL HYSTERECTOMY WITH BILATERAL SALPINGO-OOPHORECTOMY -
A. ENDOMETRIAL ADENOCARCINOMA, ENDOMETRIOID TYPE, FIGO GRADE 2, NUCLEAR GRADE 2, WITH FOCAL SQUAMOUS DIFFERENTIATION, IN THE BACKGROUND OF ATYPICAL COMPLEX HYPERPLASIA.
B. ENDOMETRIOID CARCINOMA IS LOCATED ON THE ANTERIOR ASPECT OF ENDOMETRIUM, MEASURING 3 X 1.5 X 1.5 CM (GROSS MEASUREMENT).
C. ENDOMETRIOID CARCINOMA SHOWS EXOPHYTIC GROWTH WITH FOCAL SUPERFICIAL MYOMETRIAL INVASION, 0.2 CM INVASION OF MYOMETRIUM IN THE THICKNESS OF 1.5 CM MYOMETRIUM.
D. NO LYMPH-VASCULAR INVASION NOTED.
E. PROLIFERATED ENDOMETRIUM POLYP (2.5 CM IN LARGEST DIMENSION).
F. MYOMETRIUM WITH LEIOMYOMA (0.9 CM).
G. CERVIX WITH MILD ENDOCERVICITIS, NEGATIVE FOR CARCINOMA.
H. LEFT AND RIGHT OVARIES WITH BENIGN MÜLLERIAN GLANDS.
I. LEFT AND RIGHT FALLOPIAN TUBES, UNREMARKABLE.

PART 4: EXTERNAL ILIAC LYMPH NODE, LEFT, BIOPSY -
THREE LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA.

PART 5: OBTURATOR LYMPH NODE, LEFT, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA.

PART 6: COMMON ILIAC LYMPH NODE, LEFT, BIOPSY -
ADIPOSE TISSUE, NO LYMPH NODE IDENTIFIED.

PART 7: PERIAORTIC LYMPH NODE LOW, LEFT, BIOPSY -
FIBROADIPOSE TISSUE, NO LYMPH NODE IDENTIFIED.

PART 8: PERIAORTIC LYMPH NODE HIGH, LEFT, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA

PART 9: EXTERNAL ILIAC LYMPH NODE, RIGHT, BIOPSY -
FIVE LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA.

PART 10: OBTURATOR LYMPH NODE, RIGHT, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA.

PART 11: COMMON ILIAC LYMPH NODE, RIGHT, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA.

PART 12: PERIAORTIC LYMPH NODE, RIGHT, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA.

PART 13: RECTOSIGMOID NODULE, BIOPSY -
TWO LYMPH NODES AND FRAGMENT OF COLONIC MUCOSA, NEGATIVE FOR METASTATIC CARCINOMA.

PART 14: OMENTUM, BIOPSY -
FIBROADIPOSE TISSUE, NEGATIVE FOR ADENOCARCINOMA.

COMMENT:
Pelvic wash is negative for metastatic carcinoma

per 5/3/11

[page 2 of 2]
CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL TUMORS: HYSTERECTOMY SPECIMENS
TUMOR TYPE: Endometroid adenocarcinoma, NOS

HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]:

ARCHITECTURAL GRADE: Moderately differentiated (FIGO 2)

NUCLEAR GRADE: Moderately differentiated

Grade 2

TUMOR SIZE: Maximum dimension: 3 cm

PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:

DEPTH OF INVASION:** Anterior endomyometrium: 100 %

ANGIOLYMPHATIC INVASION: Less than 1/2 thickness of myometrium

PRE-NEOPLASTIC CONDITIONS: No

OTHER: Complex endometrial hyperplasia with atypia

LYMPH NODES POSITIVE: (epithelial, smooth muscle, others), Endometrial polyp, Leiomyoma

LYMPH NODES EXAMINED: Number of lymph nodes positive:: 0

T STAGE, PATHOLOGIC: Total number of lymph nodes examined: 15

N STAGE, PATHOLOGIC: pT1b

M STAGE, PATHOLOGIC: pN0

FIGO STAGE: pMX

IB

Source: NCI Genomic Data Commons file 5b651b1a-807b-427a-975c-f0ce12d06117 (TCGA-BG-A0MI.1A0F6DD8-22A2-4A00-8AAD-04710DBBDFED.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).